Somatic mutation profile of tumor specimen MBCProject_7559_T1_WES (aliquot MBCProject_7559_T1_WES_1) from CMI case MBCProject_7559, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.2 years (22,724 days).
Specimen MBCProject_7559_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fd35dd6-f91e-4ed4-b559-54ac83437228.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_7559_SALIVA (Saliva), aliquot MBCProject_7559_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/850f5023-9533-40fb-a104-750a2450a49f

The open-access MAF lists 52 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 19, Missense Mutation 11, Silent 4, In Frame Del 4, RNA 3, 3'Flank 3, Frame Shift Del 3, 5'Flank 2, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FASN | c.4385G>A p.R1462Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs140112183; ClinVar: uncertain significance; called by mutect2, varscan2
- MTMR8 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66392602; called by mutect2, varscan2
- MYO3A | c.2848C>T p.R950C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs78316055; called by mutect2, varscan2
- SPATA33 | c.166del p.A56Pfs*19 | Frame Shift Del (DEL) | VAF 2/18 reads (11%) | catalogued as rs772165475; called by mutect2, varscan2
- ADGRG2 | c.302del p.S101* (on ENST00000379869 / NM_001079858.3; = p.S98* on NM_005756.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- BAZ2B | c.3400G>A p.E1134K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.066); called by muse, varscan2
- CCDC40 | c.1641G>T p.K547N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- DENND6B | c.1191_1202del p.R398_K401del | In Frame Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- DLAT | c.561_584del p.Q190_P197del | In Frame Del (DEL) | VAF 2/17 reads (12%) | called by mutect2, varscan2*
- ECEL1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRF2 | c.387dup p.E130Rfs*5 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- NUDCD1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- PABPC1L | c.885_896del p.N295_V298del | In Frame Del (DEL) | VAF 3/13 reads (23%) | called by mutect2, varscan2
- PEX5 | c.1773_1781del p.P592_G594del (on ENST00000420616; = p.P584_G586del on NM_000319.5) | In Frame Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PLD5 | c.1035G>T p.M345I (on ENST00000442594; = p.M283I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- SPATA31D1 | c.416_432del p.D139Vfs*23 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, varscan2
- TTN | c.18623C>A p.A6208E (on ENST00000591111; = p.A5281E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | PolyPhen benign (0.359); called by muse, mutect2, varscan2
- UCHL5 | c.435-23_453del p.X145_splice | Splice Site (DEL) | VAF 5/19 reads (26%) | called by mutect2, varscan2*
- USP29 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, varscan2
- ARFGEF3 | c.2190C>T p.N730= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs372790539; called by mutect2, varscan2
- CELSR1 | c.2805C>T p.D935= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs376784043; called by mutect2, varscan2
- DLL3 | c.741C>G p.L247= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- TTF1 | c.2685T>C p.S895= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1334807300, COSV57502936; called by muse, varscan2
- AC114741.1 | n.129G>A | RNA (SNP) | VAF 6/34 reads (18%) | catalogued as rs1461493584; called by muse, mutect2, varscan2
- ACTR6 | c.379+1009A>G | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV104386656; called by mutect2, varscan2
- ADAM10 | c.207-16014C>A | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, varscan2
- ANK3 | c.2615-1265A>G | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- C2orf74 | chr2:61159339 T>C | 5'Flank (SNP) | VAF 8/28 reads (29%) | catalogued as rs1471900258; called by muse, varscan2
- C8orf44-SGK3 | c.-121-26068C>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- CASP8 | chr2:201286642 A>G | 3'Flank (SNP) | VAF 8/54 reads (15%) | catalogued as COSV51858093; called by muse, varscan2
- CDK10 | chr16:89682766 C>G | 5'Flank (SNP) | VAF 3/17 reads (18%) | called by mutect2, varscan2
- CROCC2 | c.*21_*66del | 3'UTR (DEL) | VAF 5/8 reads (63%) | called by mutect2, varscan2*
- CYP3A43 | c.670+362G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs921142636; called by muse, mutect2, varscan2
- DYNC1LI1 | c.220+3639A>G | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs191820052; called by mutect2, varscan2
- ETFA | c.664+732T>C | Intron (SNP) | VAF 15/78 reads (19%) | called by muse, varscan2
- HMGN2 | c.91-14C>T | Intron (SNP) | VAF 3/15 reads (20%) | catalogued as rs1243505113; called by muse, varscan2
- LACTB2 | c.286+919C>A | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs1480173173, COSV52570280; called by muse, varscan2
- LINC00303 | n.110C>T | RNA (SNP) | VAF 8/45 reads (18%) | called by muse, varscan2
- MAGI3 | c.1077-1186A>G | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as rs1333820875; called by muse, varscan2
- MKRN2OS | chr3:12539174 T>C | 3'Flank (SNP) | VAF 12/94 reads (13%) | called by muse, varscan2
- PCMT1 | c.230-5448A>C | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs1470266391; called by muse, mutect2, varscan2
- PDXK | c.142+2862C>A | Intron (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- RABGEF1 | c.219-1518T>A | Intron (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
- RABGEF1 | c.635-511A>T | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs1331709854; called by muse, varscan2
- RBMS2 | c.543-881A>G | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1326655121; called by muse, mutect2
- SEC14L3 | c.54+658T>A | Intron (SNP) | VAF 12/43 reads (28%) | called by mutect2, varscan2
- SNX29P2 | n.1156A>G | RNA (SNP) | VAF 14/68 reads (21%) | catalogued as rs1430353079; called by muse, varscan2
- THEM4 | c.287-807A>G | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as rs1483716190, COSV64296099; called by mutect2, varscan2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- VPS35L | c.434-739A>G | Intron (SNP) | VAF 10/114 reads (9%) | called by muse, varscan2
- ZNF273 | c.326-4267T>C | Intron (SNP) | VAF 10/78 reads (13%) | called by muse, varscan2
